Somatic mutation profile of tumor specimen TCGA-QH-A6CV-01A (aliquot TCGA-QH-A6CV-01A-11D-A31L-08) from TCGA case TCGA-QH-A6CV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.9 years (18,955 days).
Specimen TCGA-QH-A6CV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4822d025-16a7-4589-97ef-bfd30e5696b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6CV-10A (Blood Derived Normal), aliquot TCGA-QH-A6CV-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6acb7327-7100-4b6b-84ab-9a489dbdcc42

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 31, Silent 19, Nonsense Mutation 7, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV53203034; called by muse, mutect2, varscan2
- ADAMTS15 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1161416766, COSV100143276; called by muse, mutect2, varscan2
- ADAP1 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56218688, COSV99762942; called by muse, mutect2, varscan2
- ADI1 | c.183C>A p.Y61* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100537736; called by muse, mutect2, varscan2
- ARHGAP26 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99190556; called by muse, mutect2, varscan2
- CD163L1 | c.3578G>A p.S1193N | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1565778653, COSV100549940; called by muse, mutect2, varscan2
- CLK4 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as rs368747027, COSV60318228; called by muse, mutect2, varscan2
- CPXCR1 | c.110A>C p.D37A | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99342105; called by muse, mutect2, varscan2
- CWC15 | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as COSV99688482; called by muse, mutect2
- FLT4 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV56116314; called by muse, mutect2, varscan2
- HPS5 | c.2665G>A p.E889K (on ENST00000349215 / NM_181507.2; = p.E775K on NM_007216.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV100752262; called by muse, mutect2, varscan2
- INA | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100878606; called by muse, mutect2, varscan2
- KLRB1 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV99987228; called by muse, mutect2
- LRRC15 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.817); catalogued as rs530171790, COSV61651587; called by muse, mutect2, varscan2
- MAST1 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99262690; called by mutect2, varscan2
- MINK1 | c.3071G>A p.C1024Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99544780; called by muse, mutect2, varscan2
- MTRR | c.2172G>A p.W724* (on ENST00000264668; = p.W697* on NM_002454.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/131 reads (5%) | catalogued as COSV99241556; called by muse, mutect2
- MYO1B | c.1555-1G>A p.X519_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100268956; called by muse, mutect2, varscan2
- NTF3 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.08); catalogued as rs1565398981, COSV58418537; called by muse, mutect2
- OR10J3 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100171694; called by muse, mutect2, varscan2
- OR2T6 | c.817G>T p.V273F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1343080265, COSV100861527; called by muse, mutect2, varscan2
- OR2Z1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs781846318, COSV100136398; called by muse, mutect2, varscan2
- OR4K15 | c.338G>A p.R113H (on ENST00000305051; = p.R89H on NM_001005486.1) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139377821, COSV100520989; called by muse, mutect2, varscan2
- OR52M1 | c.368A>C p.D123A | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100798576, COSV64172135; called by muse, mutect2, varscan2
- PCNX2 | c.4501C>T p.Q1501* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as rs1237727337, COSV99266946; called by muse, mutect2, varscan2
- PKHD1 | c.8332C>T p.P2778S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1286456861, COSV100582477; called by muse, mutect2, varscan2
- PPFIA3 | c.882G>A p.A294= | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as rs1414612975, COSV100494834; called by muse, mutect2, varscan2
- PRAG1 | c.4066G>A p.D1356N | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100422074; called by muse, mutect2, varscan2
- PROZ | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs777529860, COSV61439437; called by muse, mutect2, varscan2
- PURG | c.915T>A p.C305* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100230423; called by muse, mutect2, varscan2
- RANBP9 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.106); catalogued as rs756235885, COSV50581043; called by mutect2, varscan2
- RB1CC1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as rs757154137, COSV50243249; called by muse, mutect2, varscan2
- RTTN | c.2126G>A p.W709* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99731904; called by muse, mutect2, varscan2
- SELL | c.290G>A p.R97H (on ENST00000650983; = p.R84H on NM_000655.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs765158610; called by muse, mutect2
- SERPINB12 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777575587, COSV99501585; called by muse, mutect2, varscan2
- THSD7A | c.3676G>A p.V1226I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as COSV101439738; called by muse, mutect2
- TP53I3 | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99475397; called by muse, mutect2, varscan2
- TRPC7 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100725638; called by muse, mutect2
- UBASH3A | c.938C>A p.A313D | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99369469; called by muse, mutect2, varscan2
- ZGRF1 | c.6095G>C p.R2032T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101500593; called by muse, mutect2, varscan2
- ACACA | c.339-2A>G p.X113_splice | Splice Site (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- ADCK2 | c.921C>T p.S307= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs375145073, COSV99301307; called by muse, mutect2, varscan2
- CILP2 | c.1635C>T p.A545= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as rs887620296, COSV52273201, COSV99364550; called by muse, mutect2, varscan2
- CSF2 | c.33T>G p.T11= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV99735664; called by muse, mutect2, varscan2
- ERBB4 | c.510A>G p.P170= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs1450712101, COSV99620757; called by muse, mutect2, varscan2
- GRM8 | c.2211G>A p.R737= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100282017; called by muse, mutect2, varscan2
- KCNG1 | c.309C>T p.N103= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV65368714; called by muse, mutect2, varscan2
- KRT33A | c.192C>T p.N64= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as rs144512034; called by muse, mutect2
- LGI3 | c.966C>T p.D322= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs1220589250, COSV100102978; called by muse, mutect2, varscan2
- OCA2 | c.1017G>A p.A339= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs939640240, COSV100667404; called by muse, mutect2, varscan2
- OR52E2 | c.117C>T p.I39= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs767176065, COSV58612936; called by muse, mutect2, varscan2
- PRAMEF14 | c.573G>A p.P191= | Silent (SNP) | VAF 53/293 reads (18%) | catalogued as rs1379898711; called by muse, mutect2, varscan2
- RASGRF1 | c.1674G>A p.P558= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs146264269; called by muse, mutect2, varscan2
- RXFP1 | c.1158T>G p.V386= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100313682; called by muse, mutect2, varscan2
- SLC52A1 | c.168G>A p.A56= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs566207091, COSV99643367; called by muse, mutect2, varscan2
- SLC5A1 | c.594G>A p.A198= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs184213779, COSV56688485, COSV99833335; called by muse, mutect2, varscan2
- SSH2 | c.2964G>A p.R988= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99281824; called by muse, mutect2, varscan2
- TBC1D2 | c.2424G>T p.R808= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100579830; called by muse, mutect2, varscan2
- TTLL8 | c.864G>A p.T288= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs372593700; called by muse, mutect2, varscan2
- ZNF358 | c.984C>T p.F328= | Silent (SNP) | VAF 87/166 reads (52%) | catalogued as COSV51173834; called by muse, mutect2, varscan2
